Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A8HG, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A8HG-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

FINAL DIAGNOSIS:

RADICAL CYSTECTOMY WITH FIRST STAGE INFLATABLE PENILE PROSTHESIS (IPP):

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS

- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

APICAL URETHRAL MARGIN (C):

FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

BLADDER AND PROSTATE (D):

GROSS DIAGNOSIS (INTRAOPERATIVE):

- URINARY BLADDER TUMOR MEASURES 4.5 X 3 X 2 CM INVOLVING LEFT POSTEROLATERAL WALL AND LEFT URETEROVESICAL JUNCTION, EXTENSION THROUGH THE MUSCULARIS PROPRIA TO THE PERIVESICAL SOFT TISSUE

FINAL DIAGNOSIS:

BLADDER (D):

- POORLY DIFFERENTIATED, INVASIVE UROTHELIAL CARCINOMA WITH SQUAMOUS AND CLEAR CELL FEATURES, GRADE 4/4, INVOLVING LEFT POSTEROLATERAL WALL AND LEFT URETEROVESICAL JUNCTION, EXTENSION THROUGH THE MUSCULARIS PROPRIA TO THE PERIVESICAL SOFT TISSUE
- SURGICAL RESECTION MARGINS ARE FREE OF TUMOR (CLOSEST POSTEROLATERAL INKED PERIPHERAL MARGIN IS 1.2 CM)
- UROTHELIAL CARCINOMA IN-SITU (FLAT LESION) IDENTIFIED
- LYMPHOVASCULAR SPACE INVASIONS PRESENT
- NON-NEOPLASTIC BLADDER SHOWS UROTHELIAL HYPERPLASIA WITH REACTIVE CHANGES AND CHRONIC INFLAMMATION

PROSTATE (D):

- SMALL FOCUS OF WELL DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3+2=5, IN THE RIGHT POSTERIOR MID-PROSTATE WITH CLEAR MARGIN (D27)
- NO LYMPHOVASCULAR OR PERINEURAL INVASIONS IDENTIFIED
- MULTIPLE FOCI OF HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN II-III)
- BENIGN GLANDULAR AND STROMAL HYPERPLASIA AND FOCAL ATROPHY PRESENT

RIGHT PARACAVAL LYMPH NODES (E):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT PARA-AORTIC LYMPH NODES (F):

- NO MALIGNANCY IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

LEFT COMMON ILIAC LYMPH NODES (G):

- NO MALIGNANCY IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

RIGHT COMMON ILIAC LYMPH NODES (H):

- NO MALIGNANCY IDENTIFIED IN 9 LYMPH NODES EXAMINED (0/9)

CLCC
ICD-O-3
Carcinoma, urothelial NOS 8124/3
path
Carcinoma, urothelial w/ squamous
clear cell features
8310/3
Code to highest 8310/3
Site: Bladder NOS
667.9
Jan 11/23/14

Pw TSS, squamous cell
is 0% and clear cell
is 40%.

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

RIGHT EXTERNAL ILIAC LYMPH NODES (I):

- NO MALIGNANCY IDENTIFIED IN 4 LYMPH NODES EXAMINED (0/4)

RIGHT LYMPH NODE OF CLOQUET (J):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODES (K):

- NO MALIGNANCY IDENTIFIED IN 12 LYMPH NODES EXAMINED (0/12)

LEFT EXTERNAL ILIAC LYMPH NODES (L):

- NO MALIGNANCY IDENTIFIED IN 4 LYMPH NODES EXAMINED (0/4)

LEFT LYMPH NODE OF CLOQUET (M):

- NO MALIGNANCY IDENTIFIED IN 4 LYMPH NODES EXAMINED (0/4)

LEFT OBTURATOR/HYPOGASTRIC LYMPH NODES (N):

- NO MALIGNANCY IDENTIFIED IN 6 LYMPH NODES EXAMINED (0/6)

RIGHT PRE SCIATIC LYMPH NODES (O):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

PRESACRAL LYMPH NODES (P):

- NO MALIGNANCY IDENTIFIED IN 3 LYMPH NODES EXAMINED (0/3)

LEFT PRE SCIATIC LYMPH NODES (Q):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT PROXIMAL URETER (R):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

LEFT PROXIMAL URETER (S):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

PATHOLOGIC TNM STAGE (BLADDER): pT3bN0Mx.

PATHOLOGIC TNM STAGE (PROSTATE): pT1aN0Mx

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

AFS: Right distal ureter:

- Negative

BFS: Left distal ureter:

- Negative

CFS: Apical urethral margin:

- Negative

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter." It consists of a single fragment of tan tissue measuring 0.2 cm long and 0.3 cm in diameter. The specimen is entirely submitted for frozen section evaluation in cassette AFS.

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

B: The specimen is received fresh from the O.R. and labeled "Left ureter." It consists of a single fragment of tissue measuring 0.3 cm long and 0.3 cm in diameter. The specimen is entirely submitted for frozen section evaluation in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Apical urethral margin F/S." It consists of two strips of tan-pink tissue measuring 1.5 x 0.5 x 0.2 cm in aggregate. The specimen is submitted for frozen section evaluation in cassette CFS.

D: The specimen is received fresh from the O.R. and labeled "Bladder/prostate." It consists of a cystoprostatectomy specimen measuring overall 27 x 13 x 6 cm. Attached is a bladder that measures 6 x 4.5 x 2 cm with a flap of peritoneal fat measuring 15 x 15 x 2 cm. The peritoneal surface is smooth, glistening and grossly uninvolved. The radial surface is inked in black and the specimen is opened along the anterior surface with a Y-shaped incision. Opening the specimen reveals a large tumor attached to the left lateral wall measuring 4.5 x 3 x 2 cm. The tumor invades deeply through the muscularis propria into the perivesical fat. The tumor surrounds the left ureterovesical junction. The right ureterovesical junction is grossly unremarkable. The remaining urinary bladder mucosa is tan, wrinkled, smooth and grossly unremarkable. The right distal ureter is smooth and grossly unremarkable. The right distal ureter measures 4 cm long and 0.5 cm in circumference. The left distal ureter is grossly dilated and measures 4.5 cm long and 1.2 cm in circumference. Attached is a prostate that measures 5 x 4 x 2.5 cm. The prostatic urethra measures 3.5 cm long and 3 cm in circumference. The verumontanum measures 0.5 x 0.5 x 0.4 cm and is grossly unremarkable. The urethral mucosal surface is smooth, glistening and grossly unremarkable. Serial section reveals a tan prostatic parenchyma showing multiple variably sized nodules. The nodules are located centrally and show the characteristic whorled appearance of benign prostatic hypertrophy. The bilateral seminal vesicles are identified and are grossly unremarkable. Dissection and palpation through the perivesical fat reveals only yellow adipose tissue. No grossly identifiable lymph nodes are present. Representative sections are submitted in 30 cassettes.

E: The specimen is received in formalin and labeled "Right paracaval LN." It consists of a single fragment of yellow-tan fibroadipose tissue measuring 1 x 1 x 0.5 cm. The specimen is dissected for lymph nodes. A few lymph nodes are identified grossly. The specimen is entirely submitted in one cassette.

F: The specimen is received in formalin and labeled "Left para-aortic LN." It consists of a single fragment of yellow-tan fibroadipose tissue. The specimen is dissected for lymph nodes. A few lymph nodes are identified. The specimen is entirely submitted in one cassette.

G: The specimen is received in formalin and labeled "Left common iliac LN." It consists of multiple fragments of yellow-tan fibroadipose tissue measuring 4 x 3 x 1 cm in aggregate. The specimen is dissected for lymph nodes. Several lymph nodes are identified. The specimen is entirely submitted in four cassettes.

H: The specimen is received in formalin and labeled "Right common iliac LN." It consists of multiple fragments of yellow-tan fibroadipose tissue measuring 4 x 4 x 2 cm in aggregate. The specimen is dissected for lymph nodes. Several lymph nodes are identified. The largest measures 1 x 0.5 x 0.5 cm. Cut surface of the largest lymph node is tan, smooth and grossly unremarkable. Representative sections are submitted in five cassettes.

I: The specimen is received in formalin and labeled "Right external iliac LN." It consists multiple fragments of yellow-tan fibroadipose tissue measuring 5 x 5 x 4 cm in aggregate. The specimen is dissected for lymph nodes. Several lymph nodes are identified. The largest measures 1.4 x 1 x 0.5 cm. Representative sections

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

are submitted in five cassettes.

J: The specimen is received in formalin and labeled "Right LN of Cloquet." It consists of a single fragment of yellow-tan fibroadipose tissue measuring 1 x 1 x 1 cm. The specimen is dissected for lymph nodes. A single lymph node is identified and measures 0.8 x 0.7 x 0.5 cm. Lymph node is bisected and submitted entirely in one cassette.

K: The specimen is received in formalin and labeled "Right obturator/hypogastric LN." It consists of multiple fragments of yellow-tan fibroadipose tissue measuring 6 x 5 x 4 cm in aggregate. The specimen is dissected for lymph nodes. Several lymph nodes are identified. The largest node measures 1 x 0.5 x 0.5 cm. The cut surface of the largest lymph node is tan, smooth and grossly unremarkable. Representative sections are submitted in five cassettes.

L: The specimen is received in formalin and labeled "Left external iliac LN." It consists of multiple fragments of lobulated fatty tissue measuring 5 x 5 x 4 cm. The specimen is dissected for lymph nodes. Several lymph nodes are identified. The largest lymph node measures 2.5 x 1 x 0.5 cm. The cut surface of the largest lymph node is fatty tan and grossly unremarkable. Representative sections are submitted in five cassettes.

M: The specimen is received in formalin and labeled "Left LN of Cloquet." It consists of a single fragment of tan tissue measuring 1 x 0.5 x 0.5 cm. The specimen is dissected for lymph nodes. A single lymph node is identified. The cut surface is tan, smooth and grossly unremarkable. Lymph node is bisected and entirely submitted in one cassette.

N: The specimen is received in formalin and labeled "Left obturator/hypogastric LN." It consists of multiple fragments of yellow-tan fibroadipose tissue measuring 5 x 4 x 3 cm in aggregate. The specimen is dissected for lymph nodes. Several lymph nodes are identified. The largest one measures 1 x 0.5 x 0.4 cm. The cut surface of the largest lymph node is yellow-tan fatty and grossly unremarkable. Representative sections are submitted in five cassettes.

O: The specimen is received in formalin and labeled "Right presciatic LN." It consists of multiple fragments of tan-yellow fat measuring 1 x 1 x 1 cm in aggregate. The specimen is dissected for lymph nodes. A few lymph nodes are identified. The specimen is entirely submitted in one cassette.

P: The specimen is received in formalin and labeled "Presacral LN." It consists of a single large fragment of yellow-tan fibroadipose tissue measuring 5 x 5 x 1 cm. The specimen is dissected for lymph nodes. Several lymph nodes are identified. The largest node measures 1 x 1 x 0.5 cm. Cut surface of the largest lymph node is tan and unremarkable. Representative sections are submitted in three cassettes.

Q: The specimen is received in formalin and labeled "Left presciatic LN." It consists of multiple fragments of yellow-tan fibroadipose tissue measuring 2 x 1 x 1 cm in aggregate. The specimen is dissected for lymph nodes. Two lymph nodes are identified. Representative sections are submitted in one cassette.

R: The specimen is received in formalin and labeled "Right proximal ureter." It consists of a single fragment of pink tissue measuring 0.5 x 0.4 x 0.2 cm. Entirely submitted in one cassette.

S: The specimen is received in formalin and labeled "Left proximal ureter." It consists of a single fragment of pink tissue measuring 1.5 x 0.5 x 0.5 cm. Entirely submitted in one cassette.

[page 5 of 6]
Collected:
Ordered by:

SECTIONS:

AFS: frozen section, right distal ureter all embedded
BFS: frozen section, left distal ureter all embedded
CFS: frozen section, apical urethral margin all embedded
D1: anterior bladder wall
D2: posterior bladder wall
D3: right lateral wall
D4: left lateral wall and tumor
D5: dome of the bladder
D6: right ureterovesical junction
D7: left ureterovesical junction
D8: right ureter margin
D9: left ureter margin
D10-12: trigone and bladder neck
D13, 14: sections of tumor with adjacent normal bladder mucosa
D15, 16: tumor and deep black inked margin
D17: all tumor and black inked margin
D18-21: representative sections of the different areas of the tumor
D22: right perivesical fat
D23: left perivesical fat
D24: distal urethral margin
D25: right distal prostate
D26: left distal prostate
D27: right posterior midprostate
D28: left posterior midprostate
D29: right posterior proximal prostate with seminal vesicle
D30: left posterior proximal prostate with seminal vesicle
E: right paracaval lymph nodes all embedded
F: left para-aortic lymph nodes all embedded
G1-4: left common iliac lymph nodes all embedded
H1: right common iliac lymph node
H2-5: representative sections of remaining fat and lymph node
I1: right external iliac bisected single lymph node
I2-4: additional lymph nodes
I5: representative section of the remaining fat
J: right lymph node of Cloquet
K1: right obturator/hypogastric bisected single lymph node
K2-5: representative section of the remaining tissue
L1,2: left external iliac single bisected lymph node
L3: single bisected lymph node
L4, 5: representative sections of the remaining tissue
M: left lymph node of Cloquet
N1: left obturator/hypogastric single bisected lymph node
N2-5: representative sections of the remaining fibrofatty tissue
O: right presciatic lymph nodes all embedded
P1: presacral single bisected lymph node
P2,3: representative sections of the remaining tissue
Q: left presciatic lymph nodes
R: right proximal ureter all embedded
S: left proximal ureter all embedded

MICROSCOPIC DESCRIPTION:

A-C: See final microscopic-diagnoses.

D: Sections of the bladder tumor shows poorly differentiated malignant urothelial cells invading the entirely thickness of the muscularis propria into perivesical fat (D4, 7 and 13-21). There are multiple foci of lymphovascular space invasion identified (D16). The malignant cells are arranged in large sheets and nests.

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Collected:
Ordered by:

Many cells show large, pleomorphic, irregular nuclei. Malignant cells have enlarged nuclei with vesicular chromatin, prominent nucleoli and abundant pink or clear cytoplasm. A small focus of urothelial carcinoma in-situ (flat lesion) is identified (D11). Random urothelial mucosa remote from the tumor site shows multilayering of benign urothelium and sporadic reactive changes. The radial inked margin is free of tumor with the carcinoma coming within 1.2 cm from the closest inked margin (D16) in the left posterolateral perivesical soft tissue. Remaining margins, including ureteral margins, are more widely free of malignancy. Sections of the adjacent prostate show a small focus of well-differentiated invasive adenocarcinoma of the prostate in the right posterior midprostate (D27), multiple scattered nodules of benign prostatic hyperplasia. Scattered foci of high-grade prostatic intraepithelial neoplasia are identified.

E-S: See final microscopic-diagnoses.

Signed by:

ELECTRONIC SIGNATURE

ORDERING PHYSICIAN:

Ordering Physician:

Criteria:	11/4/13	Yes	No
IP/A Discrepancy			✓

Source: NCI Genomic Data Commons file 89271e2c-5b86-40e7-80e4-64e2f6bfd117 (TCGA-XF-A8HG.BBBBC7D7-4994-4B78-9C65-22B4E8C61261.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).